Surgical pathology report (de-identified scan), TCGA case TCGA-L7-A56G, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Christiana Care, specimen TCGA-L7-A56G-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinoma, Squamous Cell
NOS
8070/3

Site, Path: Esophagus, NOS
C15.9

Site, CQCF: Esophagus, distal
third C15.5

9/12/17/12

Final Surgical Pathology Report

Diagnosis

Esophageal mass, biopsy: Hypertrophic benign squamous epithelium
undermined by invasive poorly differentiated squamous cell carcinoma.
The site of origin of the malignancy is not apparent from the submitted
material.

Microscopic Description:

Microscopic examination performed.

Specimen

Esophageal mass

[page 2 of 2]
Clinical Information

Esophageal carcinoma, probable

Gross Description

Received fresh labeled "esophageal mass" are 7 soft glistening
tan-white tissues averaging 0.3 x 0.2 x 0.2 cm. AS1

12/10/12

Source: NCI Genomic Data Commons file 4c44f5bf-a96a-49b2-8e11-14f62ca9a67d (TCGA-L7-A56G.55E07B05-85A3-4ECE-A921-A99C844982F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).